Somatic mutation profile of tumor specimen TCGA-W2-A7HF-01A (aliquot TCGA-W2-A7HF-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 28.6 years (10,436 days).
Specimen TCGA-W2-A7HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6836ed6-24ab-4b33-b750-5e843056d12a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HF-10C (Blood Derived Normal), aliquot TCGA-W2-A7HF-10C-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f93fbbd1-221c-43e8-9620-16b07ad4ce4e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSX3 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 130/298 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53646574; called by muse, mutect2, varscan2
- SACS | c.8599G>T p.A2867S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TAS2R60 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
